Somatic mutation profile of tumor specimen TCGA-AA-A01I-01A (aliquot TCGA-AA-A01I-01A-02W-A00E-09) from TCGA case TCGA-AA-A01I, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage I; Age at diagnosis: 76.0 years (27,759 days).
Specimen TCGA-AA-A01I-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 03804e6b-d549-42cc-9290-92862a167554.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-A01I-10A (Blood Derived Normal), aliquot TCGA-AA-A01I-10A-01W-A00E-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/830fe833-d72a-4aaa-abd5-8aadfbf60442

The open-access MAF lists 116 somatic variants for this specimen: 93 protein-altering or splice-affecting, 20 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 78, Silent 20, Nonsense Mutation 7, Splice Site 3, Intron 2, Frame Shift Del 2, 3'Flank 1, Frame Shift Ins 1, Translation Start Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2805C>A p.Y935* | Nonsense Mutation (SNP) | VAF 67/246 reads (27%) | hotspot (GDC flag); catalogued as rs137854575, CD041148, CM920044, CM970086, COSV57324059, COSV57328770; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 25/66 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1636C>A p.Q546K | Missense Mutation (SNP) | VAF 54/152 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); catalogued as rs121913286, COSV55873527, COSV55882350; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCD2 | c.494G>A p.R165K | Missense Mutation (SNP) | VAF 59/272 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.889); catalogued as COSV58054638; called by muse, mutect2, varscan2
- ACACB | c.3370G>A p.G1124S | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as rs567554237, COSV58143105; called by muse, mutect2, varscan2
- ADAMTS16 | c.2141A>T p.D714V | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs1415256475, COSV57005096; called by muse, mutect2, varscan2
- ADAP2 | c.880C>T p.L294= | Splice Region (SNP) | VAF 45/134 reads (34%) | catalogued as COSV58297396; called by muse, mutect2, varscan2
- AHCTF1 | c.3161A>G p.Y1054C (on ENST00000366508; = p.Y1028C on NM_015446.5) | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100402877; called by muse, mutect2, varscan2
- AHCTF1 | c.3160T>G p.Y1054D (on ENST00000366508; = p.Y1028D on NM_015446.5) | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100402879; called by muse, mutect2, varscan2
- ANKRD20A4P | c.2024_2025insT p.K675Nfs*3 | Frame Shift Ins (INS) | VAF 8/55 reads (15%) | catalogued as COSV62007634; called by mutect2, varscan2
- ARPP21 | c.1583C>T p.P528L | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.098); catalogued as rs142886822; called by muse, mutect2
- ATP8B4 | c.3386G>T p.G1129V | Missense Mutation (SNP) | VAF 142/360 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV52723083; called by muse, mutect2, varscan2
- BAZ1B | c.3071+1G>T p.X1024_splice | Splice Site (SNP) | VAF 80/236 reads (34%) | catalogued as rs1554571044, COSV100289399; ClinVar: not provided; called by muse, mutect2, varscan2
- CACHD1 | c.1520C>A p.T507N | Missense Mutation (SNP) | VAF 58/225 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV51559289; called by muse, mutect2, varscan2
- CCT8L2 | c.634A>T p.T212S | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as COSV63463661; called by muse, mutect2, varscan2
- CD1E | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 53/151 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as rs754722731, COSV63771196; called by muse, mutect2, varscan2
- CD44 | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.329); catalogued as COSV53536305; called by muse, mutect2, varscan2
- CDH10 | c.2081C>T p.T694M | Missense Mutation (SNP) | VAF 162/459 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.046); catalogued as rs543550761, COSV100051806, COSV52594816; called by muse, mutect2, varscan2
- CENPE | c.2411A>G p.D804G | Missense Mutation (SNP) | VAF 106/315 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV54388803; called by muse, mutect2, varscan2
- CERS3 | c.824G>A p.R275H | Missense Mutation (SNP) | VAF 66/215 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs143625266, COSV99432078; called by muse, mutect2, varscan2
- COL11A1 | c.1807G>A p.D603N | Missense Mutation (SNP) | VAF 34/366 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1338412988, COSV100614232; called by muse, mutect2
- COL12A1 | c.5894G>A p.R1965H | Missense Mutation (SNP) | VAF 121/386 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs199747984, COSV59392343; called by muse, mutect2, varscan2
- DDX24 | c.2197C>T p.R733* | Nonsense Mutation (SNP) | VAF 41/153 reads (27%) | catalogued as COSV52574433; called by muse, mutect2, varscan2
- DLG2 | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 143/420 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.198); catalogued as rs756739930, COSV54679587; called by muse, mutect2, varscan2
- DMAC2 | c.70C>T p.R24C | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as rs1305294467, COSV55729539; called by muse, mutect2, varscan2
- DSEL | c.1157C>A p.P386H | Missense Mutation (SNP) | VAF 55/145 reads (38%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.931); catalogued as COSV59494169; called by muse, mutect2, varscan2
- EIF2B1 | c.251C>T p.S84F | Missense Mutation (SNP) | VAF 40/156 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.81); catalogued as COSV57459824; called by muse, mutect2, varscan2
- FAM20A | c.1301+1G>T p.X434_splice | Splice Site (SNP) | VAF 14/35 reads (40%) | catalogued as COSV99873117; called by muse, mutect2, varscan2
- GFM2 | c.461G>A p.R154Q | Missense Mutation (SNP) | VAF 66/179 reads (37%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.832); catalogued as rs371589931; called by muse, mutect2, varscan2
- GMPS | c.917G>T p.G306V | Missense Mutation (SNP) | VAF 225/747 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV55811566; called by muse, mutect2, varscan2
- GPR45 | c.17C>T p.T6M | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.425); catalogued as rs770837246, COSV51525975; called by muse, mutect2, varscan2
- GRIK3 | c.667C>T p.R223* | Nonsense Mutation (SNP) | VAF 19/49 reads (39%) | catalogued as rs971243250, COSV66142243; called by muse, mutect2, varscan2
- GUF1 | c.1598C>T p.S533F | Missense Mutation (SNP) | VAF 101/458 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55784651; called by muse, mutect2, varscan2
- HTR1A | c.1118G>C p.S373T | Missense Mutation (SNP) | VAF 82/185 reads (44%) | SIFT tolerated (0.42); PolyPhen benign (0.089); catalogued as COSV60500245, COSV60502732; called by mutect2, varscan2
- IL12RB2 | c.680C>T p.P227L | Missense Mutation (SNP) | VAF 14/155 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374006496, COSV52026731; called by muse, mutect2
- ITK | c.481C>T p.P161S | Missense Mutation (SNP) | VAF 83/261 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV70064913; called by muse, mutect2, varscan2
- KCND3 | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56175371; called by muse, mutect2, varscan2
- KDM5D | c.2302C>T p.R768* | Nonsense Mutation (SNP) | VAF 108/148 reads (73%) | catalogued as COSV58736833; called by muse, mutect2, varscan2
- KRT4 | c.1393G>A p.G465S | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.045); catalogued as rs201203112; called by muse, mutect2, varscan2
- LAMA1 | c.5547G>T p.R1849S | Missense Mutation (SNP) | VAF 36/203 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.889); catalogued as COSV67543559; called by muse, mutect2, varscan2
- LAMP5 | c.593C>T p.T198M | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.058); catalogued as rs202101525; called by muse, mutect2, varscan2
- LMO3 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 183/322 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs867223722, COSV53784856; called by muse, mutect2, varscan2
- LRGUK | c.1914C>A p.F638L | Missense Mutation (SNP) | VAF 107/323 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV53642886; called by muse, mutect2, varscan2
- MAGI1 | c.2365C>A p.P789T | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs770193154, COSV58322664; called by muse, mutect2, varscan2
- MARF1 | c.5119T>G p.S1707A | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.68); PolyPhen benign (0.015); catalogued as COSV60028287; called by muse, mutect2, varscan2
- ME1 | c.133C>A p.P45T | Missense Mutation (SNP) | VAF 145/567 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63842108; called by muse, mutect2, varscan2
- MEGF8 | c.7699C>T p.R2567W (on ENST00000251268 / NM_001271938.2; = p.R2500W on NM_001410.3) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as rs762303782, COSV52073757; called by muse, mutect2
- MTREX | c.516-1G>T p.X172_splice | Splice Site (SNP) | VAF 102/267 reads (38%) | catalogued as COSV100043326; called by muse, mutect2, varscan2
- MUC16 | c.5522C>T p.T1841I | Missense Mutation (SNP) | VAF 155/450 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as rs1180138046, COSV67489263; called by muse, mutect2, varscan2
- MUC17 | c.11870C>T p.T3957I | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV60301199; called by muse, mutect2, varscan2
- MYH4 | c.2059G>A p.A687T | Missense Mutation (SNP) | VAF 25/264 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1567702646, COSV99700034; called by muse, mutect2
- MYPN | c.3595C>T p.P1199S | Missense Mutation (SNP) | VAF 132/360 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62738375; called by muse, mutect2, varscan2
- NALCN | c.3959C>T p.T1320M | Missense Mutation (SNP) | VAF 92/307 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.934); catalogued as COSV51938547; called by muse, mutect2, varscan2
- NEXN | c.1592G>T p.R531I | Missense Mutation (SNP) | VAF 100/293 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV53937451; called by muse, mutect2, varscan2
- OR2T1 | c.218T>C p.I73T | Missense Mutation (SNP) | VAF 161/448 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.947); catalogued as COSV63542755; called by muse, mutect2, varscan2
- ORC3 | c.167C>A p.S56Y | Missense Mutation (SNP) | VAF 82/149 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.328); catalogued as COSV57643085; called by muse, mutect2, varscan2
- PCBP1 | c.299T>A p.L100Q | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs1422143141, COSV57849655, COSV57849905, COSV57849936; called by muse, mutect2, varscan2
- PCDHA9 | c.1612C>T p.R538C | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.082); catalogued as rs782219075, COSV65329183; called by muse, mutect2, varscan2
- PCDHGB1 | c.1732G>A p.A578T | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV53913871; called by muse, mutect2, varscan2
- PCDHGB4 | c.2135G>A p.R712H | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as rs1047341984, COSV53923204; called by muse, mutect2, varscan2
- PCDHGB5 | c.1535C>T p.A512V | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs759226157, COSV54018960; called by muse, mutect2, varscan2
- POTEH | c.337G>A p.G113S | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs746110226, COSV58879891; called by muse, varscan2
- PROKR1 | c.916G>A p.V306M | Missense Mutation (SNP) | VAF 37/183 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.557); catalogued as rs143892402, COSV58136477; called by muse, mutect2
- PTCHD1 | c.466G>A p.V156I | Missense Mutation (SNP) | VAF 128/148 reads (86%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs199597484, COSV65062485; ClinVar: benign; called by muse, mutect2, varscan2
- R3HDM1 | c.2485G>A p.G829R | Missense Mutation (SNP) | VAF 52/100 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1053999323, COSV51527064; called by muse, mutect2, varscan2
- RAPGEF5 | c.965C>T p.T322M | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.167); catalogued as rs557224504, COSV59780295; called by muse, mutect2, varscan2
- RNF20 | c.1711C>T p.R571* | Nonsense Mutation (SNP) | VAF 67/466 reads (14%) | catalogued as rs142811207; called by muse, mutect2, varscan2
- RNF43 | c.1484C>A p.S495Y | Missense Mutation (SNP) | VAF 52/155 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs763525805, COSV68457637, COSV68460081; called by muse, mutect2, varscan2
- SEL1L2 | c.680C>T p.S227L | Missense Mutation (SNP) | VAF 96/370 reads (26%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.503); catalogued as rs372260139; called by muse, mutect2, varscan2
- SIGLEC6 | c.874G>A p.A292T | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.058); catalogued as rs1420960508, COSV58436828; called by muse, mutect2, varscan2
- SLC12A6 | c.2027T>A p.F676Y (on ENST00000354181 / NM_001365088.1; = p.F625Y on NM_005135.2) | Missense Mutation (SNP) | VAF 121/354 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); catalogued as COSV51631053; called by muse, mutect2, varscan2
- SLC25A28 | c.664G>A p.G222R | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.031); catalogued as rs764564076, COSV65125653; called by muse, mutect2, varscan2
- SLC8A1 | c.2009C>T p.P670L | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs776057619, COSV100243775, COSV60492105; called by muse, mutect2
- SLK | c.3427C>T p.R1143C | Missense Mutation (SNP) | VAF 67/225 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775081236, COSV59828506; called by muse, mutect2, varscan2
- SMG1 | c.4463C>A p.T1488N | Missense Mutation (SNP) | VAF 147/352 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.101); catalogued as rs753628889, COSV67174464; called by muse, mutect2, varscan2
- SPATA16 | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 197/591 reads (33%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.923); catalogued as rs778336962, COSV63532712; called by muse, mutect2, varscan2
- TCF7L2 | c.726T>G p.Y242* (on ENST00000355995 / NM_001367943.1; = p.Y219* on NM_030756.5) | Nonsense Mutation (SNP) | VAF 20/79 reads (25%) | catalogued as COSV53347931; called by muse, mutect2, varscan2
- TENM3 | c.6605C>T p.T2202M | Missense Mutation (SNP) | VAF 58/171 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.353); catalogued as rs146065963, COSV69310305; called by muse, mutect2, varscan2
- TMEM184C | c.871G>A p.G291R | Missense Mutation (SNP) | VAF 129/355 reads (36%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.938); catalogued as rs765651247, COSV56854640, COSV99669623; called by muse, mutect2, varscan2
- TNR | c.2260G>A p.V754I | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs370853708; called by muse, mutect2, varscan2
- TTC37 | c.4612C>A p.L1538I | Missense Mutation (SNP) | VAF 51/168 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV62456587; called by muse, mutect2, varscan2
- TTN | c.3094G>A p.V1032M (on ENST00000591111; = p.V986M on NM_003319.4) | Missense Mutation (SNP) | VAF 48/100 reads (48%) | PolyPhen probably damaging (0.999); catalogued as rs768869901, COSV60301008; called by muse, mutect2, varscan2
- UBE3C | c.113A>C p.K38T | Missense Mutation (SNP) | VAF 63/171 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61955370; called by muse, mutect2, varscan2
- USHBP1 | c.1160G>A p.R387K | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.07); catalogued as COSV53105932; called by muse, mutect2, varscan2
- VN1R1 | c.938T>A p.V313D | Missense Mutation (SNP) | VAF 79/201 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV58091691; called by muse, mutect2
- YARS2 | c.1241G>A p.R414H | Missense Mutation (SNP) | VAF 34/157 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as rs762786998, COSV61402505; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZBED2 | c.529del p.R177Gfs*15 | Frame Shift Del (DEL) | VAF 20/96 reads (21%) | catalogued as COSV99342913; called by mutect2, pindel, varscan2
- ZNF287 | c.145C>T p.R49* | Nonsense Mutation (SNP) | VAF 58/163 reads (36%) | catalogued as rs759184030, COSV67689059; called by muse, mutect2, varscan2
- ZNF426 | c.1004C>A p.P335H | Missense Mutation (SNP) | VAF 12/326 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99464847; called by muse, mutect2
- ZNF442 | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 126/314 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.899); catalogued as rs568755118, COSV54421654; called by mutect2, varscan2
- B2M | c.3_5del p.MS1_?2 | Translation Start Site (DEL) | VAF 8/41 reads (20%) | called by mutect2, varscan2
- HSD17B12 | c.4del p.E2? | Frame Shift Del (DEL) | VAF 16/66 reads (24%) | called by mutect2, pindel, varscan2
- PSAPL1 | c.623A>G p.N208S | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT tolerated (0.83); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ACSM3 | c.1740G>A p.K580= | Silent (SNP) | VAF 18/179 reads (10%) | catalogued as COSV55504605, COSV99184002; called by muse, mutect2
- ADGRG7 | c.1059T>C p.D353= | Silent (SNP) | VAF 38/140 reads (27%) | catalogued as COSV99840327; called by muse, mutect2
- ANKRD34B | c.717G>A p.G239= | Silent (SNP) | VAF 6/127 reads (5%) | catalogued as COSV100103294; called by muse, mutect2
- CORIN | c.900C>T p.D300= | Silent (SNP) | VAF 17/232 reads (7%) | catalogued as rs767155241, COSV56696690; called by muse, mutect2
- FAM181A | c.108G>A p.S36= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as rs750747760, COSV99967719; called by muse, mutect2, varscan2
- FBN1 | c.7050C>T p.I2350= | Silent (SNP) | VAF 65/157 reads (41%) | catalogued as rs772287755, COSV57312057; called by muse, mutect2, varscan2
- GABRG3 | c.543C>T p.D181= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as rs200252575, COSV61531497; called by muse, mutect2, varscan2
- HYDIN | c.600C>T p.L200= | Silent (SNP) | VAF 44/160 reads (28%) | catalogued as rs757124622, COSV55497086; called by muse, mutect2, varscan2
- INPP5A | c.1113C>T p.V371= | Silent (SNP) | VAF 25/36 reads (69%) | catalogued as rs1386698679, COSV100703973; called by muse, mutect2, varscan2
- IPO8 | c.2643G>A p.L881= | Silent (SNP) | VAF 233/435 reads (54%) | catalogued as COSV56245135; called by muse, mutect2, varscan2
- MIDEAS | c.807G>A p.P269= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as rs1344978205, COSV54095970; called by muse, mutect2, varscan2
- MLLT3 | c.1278C>T p.D426= | Silent (SNP) | VAF 89/251 reads (35%) | catalogued as COSV63501197; called by muse, mutect2, varscan2
- MOCS1 | c.612C>T p.H204= | Silent (SNP) | VAF 3/27 reads (11%) | catalogued as rs1419372576, COSV100418313; called by muse, mutect2
- OMP | c.426C>T p.L142= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as rs373450635; called by muse, mutect2, varscan2
- PCDHGA8 | c.300G>A p.P100= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as COSV53900169; called by muse, mutect2, varscan2
- PLEKHA6 | c.2895C>T p.N965= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as rs139252016; called by muse, mutect2, varscan2
- PRDM1 | c.2001G>A p.K667= | Silent (SNP) | VAF 37/158 reads (23%) | catalogued as COSV64846824; called by muse, mutect2, varscan2
- SLC7A7 | c.1269C>A p.V423= | Silent (SNP) | VAF 54/175 reads (31%) | catalogued as COSV53538200; called by muse, mutect2, varscan2
- UTRN | c.627G>A p.E209= | Silent (SNP) | VAF 49/109 reads (45%) | catalogued as COSV62346013; called by muse, mutect2, varscan2
- ZFHX4 | c.951C>T p.C317= | Silent (SNP) | VAF 92/256 reads (36%) | catalogued as rs754492746, COSV50580190, COSV50751463; called by muse, mutect2, varscan2
- EMC3-AS1 | chr3:10007512 ins T | 3'Flank (INS) | VAF 7/62 reads (11%) | called by mutect2, pindel, varscan2
- GPHN | c.729+1343A>G | Intron (SNP) | VAF 49/150 reads (33%) | catalogued as rs1325421436, COSV59491421; called by muse, mutect2, varscan2
- TTN | c.10360+5512G>T | Intron (SNP) | VAF 156/518 reads (30%) | catalogued as COSV60300999; called by muse, mutect2, varscan2
